Somatic mutation profile of tumor specimen TARGET-20-PANLKB-09A (aliquot TARGET-20-PANLKB-09A-03D) from TARGET case TARGET-20-PANLKB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,678 days).
Specimen TARGET-20-PANLKB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57574aba-d23c-4947-9377-406948664c20.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANLKB-14A (Bone Marrow Normal), aliquot TARGET-20-PANLKB-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/820b6646-82cf-4f77-8112-7542e61f83e6

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1765T>C p.Y589H | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54069256, COSV54073406; called by muse, mutect2, varscan2
- ALPK2 | c.5562A>T p.G1854= | Silent (SNP) | VAF 19/275 reads (7%) | called by muse, mutect2
